Somatic mutation profile of tumor specimen MP2PRT-PARHXX-TMP1-A (aliquot MP2PRT-PARHXX-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARHXX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Precursor B-cell lymphoblastic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,342 days).
Specimen MP2PRT-PARHXX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1677970d-1e8b-437e-8772-c34eccb6ab4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARHXX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARHXX-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e765706-dcda-4df7-8da5-045f95fb6057

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 4, Splice Site 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 47/360 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 140/460 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CACNA1B | c.6329G>A p.R2110Q | Missense Mutation (SNP) | VAF 183/632 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1307987541; called by muse, mutect2, varscan2
- DOT1L | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 187/423 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs752264656, COSV67110438; called by muse, mutect2, varscan2
- MYO5A | c.1975C>T p.R659C | Missense Mutation (SNP) | VAF 175/367 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762594836, COSV62560863; called by muse, mutect2, varscan2
- PRRC2A | c.2627T>C p.I876T | Missense Mutation (SNP) | VAF 366/783 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs760951374; called by muse, mutect2, varscan2
- PTCH1 | c.4181G>A p.R1394Q | Missense Mutation (SNP) | VAF 304/684 reads (44%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.04); catalogued as rs748812637, COSV59485570; ClinVar: uncertain significance; called by muse, varscan2
- SULF2 | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 106/247 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs777944022; called by muse, mutect2, varscan2
- TBC1D3I | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 55/443 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.046); catalogued as rs1215382910; called by muse, mutect2, varscan2
- TSHZ3 | c.834G>A p.M278I | Missense Mutation (SNP) | VAF 44/516 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as rs137987422; called by muse, mutect2
- VPS52 | c.1470C>A p.S490R | Missense Mutation (SNP) | VAF 197/417 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71403607; called by muse, varscan2
- CREBBP | c.5012C>T p.A1671V | Missense Mutation (SNP) | VAF 324/687 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- EP300 | c.5373C>G p.Y1791* | Nonsense Mutation (SNP) | VAF 185/559 reads (33%) | called by muse, mutect2, varscan2
- FAM161B | c.386G>A p.S129N (on ENST00000651776; = p.S66N on NM_152445.3) | Missense Mutation (SNP) | VAF 24/480 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.743); called by muse, mutect2
- FAM53B | c.133+1G>A p.X45_splice | Splice Site (SNP) | VAF 81/197 reads (41%) | called by muse, mutect2, varscan2
- HRNR | c.2662G>A p.G888S | Missense Mutation (SNP) | VAF 276/586 reads (47%) | SIFT tolerated (0.84); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- SLC6A15 | c.332G>A p.G111D | Missense Mutation (SNP) | VAF 133/281 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC9B2 | c.286C>T p.L96F | Missense Mutation (SNP) | VAF 115/376 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- TAF1L | c.761G>T p.R254L | Missense Mutation (SNP) | VAF 269/537 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- CXCL1 | c.21C>T p.S7= | Silent (SNP) | VAF 266/789 reads (34%) | catalogued as rs911641080; called by muse, mutect2
- FAM217B | c.504G>T p.T168= | Silent (SNP) | VAF 50/549 reads (9%) | catalogued as rs749209846; called by muse, mutect2
- PCDHGA3 | c.54G>A p.A18= | Silent (SNP) | VAF 57/393 reads (15%) | catalogued as COSV53985903; called by muse, mutect2, varscan2
- SLC9B2 | c.285T>G p.V95= | Silent (SNP) | VAF 111/371 reads (30%) | called by muse, mutect2, varscan2
- RASGRP2 | c.371+32dup | Intron (INS) | VAF 96/390 reads (25%) | catalogued as rs748688495; called by mutect2, varscan2
